Somatic mutation profile of tumor specimen TARGET-10-PAPGWN-09A (aliquot TARGET-10-PAPGWN-09A-01D) from TARGET case TARGET-10-PAPGWN, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.7 years (2,830 days).
Specimen TARGET-10-PAPGWN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 63d0aa04-1f3e-44e5-aaab-84f9a68f1c56.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPGWN-14A (Bone Marrow Normal), aliquot TARGET-10-PAPGWN-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f07eeee-6ab9-42c4-b082-53de16d9dcb1

The open-access MAF lists 28 somatic variants for this specimen: 19 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 5, Intron 3, Splice Site 1, Splice Region 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 7/29 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as rs1057519725, COSV55498939; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 10/63 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- C12orf43 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs755288501, COSV56568245; called by muse, mutect2, varscan2
- CDSN | c.755C>T p.P252L | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as CD118951; called by muse, mutect2, varscan2
- DNAH2 | c.10382G>A p.R3461Q | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as rs375708908; called by muse, mutect2, varscan2
- FBLN1 | c.1561C>T p.R521C | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs17852050, COSV99411550; called by muse, mutect2, varscan2
- GRM1 | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as COSV51154276; called by muse, mutect2, varscan2
- IL21R | c.1549dup p.R517Pfs*48 | Frame Shift Ins (INS) | VAF 24/49 reads (49%) | catalogued as rs748992699; called by mutect2, varscan2
- KY | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as rs754383672, COSV101415010; called by muse, mutect2, varscan2
- MAT1A | c.90G>A p.P30= | Splice Region (SNP) | VAF 14/93 reads (15%) | catalogued as rs757610779; called by muse, mutect2, varscan2
- MXRA5 | c.6460C>T p.R2154W | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV54226273; called by muse, mutect2
- SASH1 | c.2507G>A p.R836Q | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as rs750280402, COSV66561339, COSV66561724; called by muse, mutect2, varscan2
- SORCS2 | c.2398G>A p.V800I | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs1371818196; called by muse, mutect2, varscan2
- TADA2A | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs367602386; called by muse, mutect2, varscan2
- FMO2 | c.607C>A p.L203M | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SI | c.4160A>C p.K1387T | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLITRK1 | c.446C>A p.A149D | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- SNX4 | c.1306-1G>T p.X436_splice | Splice Site (SNP) | VAF 4/35 reads (11%) | called by muse, mutect2
- TEDC2 | c.1155G>T p.K385N | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- FMN2 | c.939G>A p.A313= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as rs1397777846; called by muse, mutect2, varscan2
- NTS | c.486A>T p.I162= | Silent (SNP) | VAF 31/69 reads (45%) | called by muse, mutect2, varscan2
- SBK1 | c.159C>T p.Y53= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as rs747755798; called by muse, mutect2, varscan2
- STAB2 | c.7641C>A p.P2547= | Silent (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- ZNF296 | c.1362C>T p.F454= | Silent (SNP) | VAF 7/11 reads (64%) | catalogued as rs776455930, COSV55519476; called by muse, mutect2, varscan2
- C11orf98 | c.-17G>T | 5'UTR (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- HLA-DMA | c.652+13C>T | Intron (SNP) | VAF 7/98 reads (7%) | called by muse, mutect2
- HOPX | c.145-161G>T | Intron (SNP) | VAF 3/19 reads (16%) | called by muse, mutect2
- MIGA1 | c.1188+151C>A | Intron (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
